TCGA case TCGA-SR-A6MX — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system; Tissue source site: Tufts Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/065f7b7a-05ee-4728-bcfc-6095357512a6

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 95 days.

Diagnoses (2)
1. Paraganglioma, malignant (the primary disease): ICD-O-3 morphology code: 8680/3; ICD-10 code: C72.9; Tissue or organ of origin: Nervous system, NOS; Site of resection or biopsy: Nervous system, NOS; Classification of tumor: primary; Age at diagnosis: 55.3 years (20,186 days); Year of diagnosis: 2013; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Retroperitoneum; Classification of tumor: Prior primary; Age at diagnosis: 41.2 years (15,052 days); Days to diagnosis: -5,134 days (-14.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -5,138 days (-14.1 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 95 days; Disease response: With Tumor.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SR-A6MX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-SR-A6MX-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SR-A6MX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SR-A6MX-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-SR-A6MX-05A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SR-A6MX-05Z: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SR-A6MX-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-SR-A6MX-06A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SR-A6MX-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SR-A6MX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: retroperitoneal; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Epidural; Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Paraganglioma; Disease detected on screening: Yes; Ct scan preop results: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: paraganglioma.
- Other malignancy form, Surgery: Other malignancy surgery type: excision.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 95 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 95 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 95 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SR-A6MX-01A-11D-A35H-01): tumor purity 0.8, ploidy 1.78, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SR-A6MX-05A-11D-A35H-01): tumor purity 0.61, ploidy 3.59, whole-genome doublings 1.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SR-A6MX-06A-11D-A35H-01): tumor purity 0.65, ploidy 3.52, whole-genome doublings 1.
